Somatic mutation profile of tumor specimen TCGA-75-7031-01A (aliquot TCGA-75-7031-01A-11D-1945-08) from TCGA case TCGA-75-7031, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-7031-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b044473a-8ac7-4fca-928e-274b08fa8e06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-7031-10A (Blood Derived Normal), aliquot TCGA-75-7031-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bfa1e21-392f-4400-be5e-74deba5cb673

The open-access MAF lists 224 somatic variants for this specimen: 164 protein-altering or splice-affecting, 53 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 53, Nonsense Mutation 13, Frame Shift Del 7, Intron 4, Splice Region 2, In Frame Del 2, Frame Shift Ins 2, RNA 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM022255, CM1510368, COSV58820077, COSV58827670; called by muse, mutect2, varscan2
- TP53 | c.844_849del p.R282_R283del | In Frame Del (DEL) | VAF 13/31 reads (42%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AARS1 | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV55747891, COSV55749807; called by muse, mutect2, varscan2
- ADAMTS1 | c.1389G>C p.L463F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53173812; called by muse, mutect2, varscan2
- ADAMTS3 | c.1174T>C p.S392P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54404117; called by muse, mutect2, varscan2
- ADGRE3 | c.952A>G p.R318G | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV53734908, COSV53735332; called by muse, mutect2, varscan2
- AHNAK | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV57232551; called by muse, mutect2, varscan2
- AL592490.1 | c.2020G>C p.V674L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as COSV69424507; called by muse, mutect2, varscan2
- ANKRD12 | c.3832G>T p.A1278S | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV50852061; called by muse, mutect2, varscan2
- ANKRD36B | c.1080G>T p.Q360H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV51537853; called by muse, mutect2, varscan2
- ANO1 | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as COSV60289900; called by muse, mutect2
- ARHGAP45 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV57436781; called by muse, mutect2, varscan2
- ASTN1 | c.2176G>A p.G726R | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV56087298; called by muse, mutect2, varscan2
- ATP7A | c.2090C>A p.S697Y | Missense Mutation (SNP) | VAF 140/344 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV58454729; called by muse, mutect2, varscan2
- ATP8B3 | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV59549203; called by muse, mutect2, varscan2
- BCL2A1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as COSV51213543; called by muse, mutect2, varscan2
- BCORL1 | c.3562C>A p.P1188T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV54408462; called by muse, mutect2, varscan2
- BVES | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58950189; called by muse, mutect2, varscan2
- CABLES1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV56937826; called by muse, mutect2, varscan2
- CARD6 | c.1063A>T p.K355* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV54569439; called by muse, mutect2, varscan2
- CCDC60 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV59551290; called by muse, mutect2, varscan2
- CD200 | c.35del p.G12Afs*9 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | catalogued as COSV59863416; called by mutect2, pindel, varscan2
- CDH12 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV66389249, COSV66451901; called by muse, mutect2, varscan2
- CDH5 | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV100439344, COSV58520266; called by muse, mutect2, varscan2
- CDH7 | c.1132T>A p.S378T | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV59895727; called by muse, mutect2, varscan2
- CDK10 | c.938C>T p.T313M (on ENST00000353379 / NM_052988.5; = p.T242M on NM_052987.4) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as rs151021544; called by muse, mutect2, varscan2
- CFHR4 | c.34T>C p.W12R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV52236260; called by muse, mutect2, varscan2
- CIDEA | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV57600957; called by muse, mutect2
- CLCN1 | c.2666A>G p.N889S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs750512826, COSV58374840; called by muse, mutect2, varscan2
- CLEC3A | c.355G>T p.E119* (on ENST00000651443; = p.E110* on NM_005752.6) | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as rs202038528, COSV55219665, COSV55219802, COSV55220651; called by muse, mutect2, varscan2
- COL11A1 | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62199330; called by muse, mutect2, varscan2
- CTCF | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs112926498, COSV50464965; called by muse, mutect2, varscan2
- CYLC1 | c.1348C>A p.P450T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV61416344; called by muse, mutect2, varscan2
- DCHS1 | c.6249A>C p.P2083= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as COSV55043495; called by muse, mutect2, varscan2
- DCTN1 | c.3689C>T p.A1230V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV62621608; called by muse, mutect2, varscan2
- DMXL1 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as COSV60721976; called by muse, mutect2, varscan2
- DOCK2 | c.3452A>T p.Q1151L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.119); catalogued as COSV56990561; called by muse, mutect2, varscan2
- DSPP | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV56817103; called by muse, mutect2, varscan2
- DSTYK | c.2012A>G p.N671S | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764174507, COSV65688612; called by muse, mutect2, varscan2
- EDIL3 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56923092, COSV99676960; called by muse, mutect2, varscan2
- EEPD1 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs748408838, COSV54203588; called by muse, mutect2, varscan2
- EFCAB12 | c.375G>T p.W125C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV58179100; called by muse, mutect2, varscan2
- EFHB | c.818G>C p.R273T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as COSV55554219; called by muse, mutect2, varscan2
- EPHA5 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56676947; called by muse, mutect2, varscan2
- ERCC6 | c.1592G>C p.G531A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV63394770; called by muse, mutect2, varscan2
- FAM135B | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50542208; called by muse, mutect2, varscan2
- FAM171B | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV59009069; called by muse, mutect2, varscan2
- FAM83D | c.1532T>G p.L511R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV54159350; called by muse, mutect2, varscan2
- FANCM | c.4871G>T p.C1624F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1457271846, COSV57507123; called by muse, mutect2, varscan2
- FAT4 | c.8331G>C p.Q2777H | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58691330, COSV58711120; called by muse, mutect2, varscan2
- FGD6 | c.2620C>G p.H874D | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV59697502; called by muse, mutect2
- FGF17 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV63925912; called by muse, mutect2, varscan2
- FOXP1 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV59555888; called by muse, mutect2, varscan2
- GGN | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs943922359, COSV53058001; called by muse, mutect2, varscan2
- GOLGA3 | c.2348A>T p.Q783L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV52644828; called by muse, mutect2, varscan2
- GPM6A | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54561978; called by muse, mutect2, varscan2
- GPR20 | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.376); catalogued as rs753556010, COSV66683908; called by muse, mutect2, varscan2
- GPR50 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 281/684 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99506862; called by muse, mutect2, varscan2
- GRIN3A | c.2080C>A p.L694M | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62458784; called by muse, varscan2
- HAX1 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV55182016; called by muse, mutect2, varscan2
- HERC5 | c.1964G>C p.S655T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1374654136, COSV52045567; called by muse, mutect2
- HGF | c.1605T>G p.C535W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55957788; called by muse, mutect2, varscan2
- HRH2 | c.119G>C p.C40S | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51576562; called by muse, mutect2, varscan2
- ICE2 | c.88A>C p.N30H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs372175361; called by muse, mutect2, varscan2
- IL9R | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376030741, COSV54902416; called by muse, mutect2, varscan2
- ILDR2 | c.289A>T p.R97W | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV54835832; called by muse, mutect2, varscan2
- IQCN | c.2828G>T p.R943L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV62747800, COSV62748805; called by muse, mutect2, varscan2
- IQSEC3 | c.3256C>G p.P1086A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1393518272, COSV58291571; called by muse, mutect2
- KCNH1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV55106509; called by muse, mutect2, varscan2
- KIFAP3 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV63037706; called by muse, mutect2, varscan2
- KIFC1 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV65737946; called by muse, mutect2
- KMT2C | c.12109A>C p.I4037L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.297); catalogued as COSV51507657; called by muse, mutect2, varscan2
- KRTAP10-11 | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV58179567; called by muse, mutect2, varscan2
- L3MBTL1 | c.1123G>A p.A375T (on ENST00000418998 / NM_001377303.1; = p.A285T on NM_015478.7) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64229753; called by muse, mutect2, varscan2
- LAMA1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101057880, COSV67537986; called by muse, mutect2, varscan2
- LMTK2 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775318231, COSV51999720, COSV52004831; called by muse, mutect2, varscan2
- LTBP3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.2); catalogued as rs1303744239, COSV57244536; called by muse, mutect2, varscan2
- LYVE1 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV56283691; called by muse, mutect2, varscan2
- MACO1 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.096); catalogued as COSV65478508; called by muse, mutect2, varscan2
- MAGEE1 | c.1696C>G p.P566A | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100819350, COSV63912291; called by muse, mutect2, varscan2
- MEAK7 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV59145713; called by muse, mutect2, varscan2
- MED14 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61358769; called by muse, mutect2, varscan2
- MME | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV64705980, COSV64711200; called by muse, mutect2, varscan2
- MYF5 | c.449del p.G150Dfs*61 | Frame Shift Del (DEL) | VAF 48/246 reads (20%) | catalogued as COSV57357264; called by mutect2, pindel, varscan2
- MYO18A | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs746302395, COSV62874174; called by muse, mutect2, varscan2
- MYRF | c.2249C>T p.S750L (on ENST00000278836 / NM_001127392.3; = p.S741L on NM_013279.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV53894521; called by muse, mutect2
- NADK | c.945A>C p.G315= | Splice Region (SNP) | VAF 5/47 reads (11%) | catalogued as COSV58277205; called by muse, mutect2, varscan2
- NALCN | c.1495A>G p.I499V | Missense Mutation (SNP) | VAF 122/179 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51968136; called by muse, mutect2, varscan2
- NLGN3 | c.2053G>T p.G685W (on ENST00000358741 / NM_181303.2; = p.G665W on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV62445504; called by muse, mutect2, varscan2
- NTRK2 | c.2150T>A p.I717N (on ENST00000323115 / NM_001369534.1; = p.I733N on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52884402; called by muse, mutect2, varscan2
- NUP188 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV65365167; called by muse, mutect2, varscan2
- OGFR | c.180G>C p.M60I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV51703018; called by muse, varscan2
- OGT | c.1768T>A p.C590S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV65482784; called by muse, mutect2, varscan2
- OGT | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.073); catalogued as rs760156553, COSV65482789; called by muse, mutect2, varscan2
- OPN1SW | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV50821984, COSV50823619; called by muse, mutect2
- OR2T27 | c.412C>A p.R138S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs145097433, COSV100788284; called by muse, mutect2, varscan2
- OR6F1 | c.514C>G p.R172G | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV100129402, COSV57469581; called by muse, mutect2, varscan2
- OR6F1 | c.159T>A p.H53Q | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57469588; called by muse, mutect2, varscan2
- OR8I2 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV56170744; called by muse, mutect2, varscan2
- OR9I1 | c.640A>C p.I214L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56927564; called by muse, mutect2, varscan2
- ORC2 | c.1194G>C p.Q398H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV52241849; called by muse, mutect2, varscan2
- PCDHB10 | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.392); catalogued as COSV53384322; called by muse, mutect2, varscan2
- PCLO | c.12643G>T p.D4215Y | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61670423; called by muse, mutect2, varscan2
- PDE1C | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1562866361, COSV100374276; called by muse, mutect2, varscan2
- PDE6B | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55331243; called by muse, mutect2, varscan2
- PEG3 | c.3442C>T p.H1148Y | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.696); catalogued as COSV55634030; called by muse, mutect2, varscan2
- PKD1L1 | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.766); catalogued as COSV56979449; called by muse, mutect2, varscan2
- PLCG2 | c.626T>A p.L209H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63874190, COSV63877050; called by muse, mutect2, varscan2
- PLCH1 | c.2193A>T p.K731N (on ENST00000340059 / NM_001130960.2; = p.K743N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58210912; called by muse, mutect2, varscan2
- PPP6R3 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV55724976, COSV55736928; called by muse, mutect2, varscan2
- PROP1 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV57645533; called by muse, mutect2, varscan2
- PSIP1 | c.1209A>G p.I403M | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761406442, COSV66255815; called by muse, mutect2, varscan2
- RAG1 | c.1061T>A p.L354Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as CD010112, COSV55028650, COSV55029154; called by muse, mutect2, varscan2
- RBM12 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs1156780822, COSV58295388; called by muse, mutect2, varscan2
- RD3 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65362964; called by muse, mutect2, varscan2
- RELN | c.9481C>A p.P3161T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59024305, COSV59036175; called by muse, mutect2, varscan2
- RELN | c.1394C>A p.S465Y | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59036184; called by muse, mutect2, varscan2
- RNF213 | c.2738G>A p.W913* | Nonsense Mutation (SNP) | VAF 35/147 reads (24%) | catalogued as COSV60630852; called by muse, mutect2, varscan2
- RPN1 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.328); catalogued as COSV99957380; called by muse, mutect2, varscan2
- RUNX1T1 | c.1127C>A p.T376N (on ENST00000265814 / NM_001198628.1; = p.T349N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/504 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56164419; called by muse, mutect2
- SCN8A | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV61993794; called by muse, mutect2
- SEC14L1 | c.1663G>T p.V555L | Missense Mutation (SNP) | VAF 80/379 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV66725750; called by muse, mutect2, varscan2
- SGIP1 | c.1516A>C p.T506P | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52779780; called by muse, mutect2, varscan2
- SGO1 | c.604A>C p.I202L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55425387; called by muse, mutect2, varscan2
- SH2B2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100159661, COSV60828064; called by muse, mutect2, varscan2
- SLC24A2 | c.1139G>T p.R380I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV53876961; called by muse, mutect2, varscan2
- SLC5A4 | c.1367C>G p.T456R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs890288192, COSV56674281; called by muse, mutect2, varscan2
- SLC6A2 | c.553T>A p.C185S | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54924006; called by muse, mutect2, varscan2
- SLC7A13 | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 110/153 reads (72%) | catalogued as COSV52537630; called by muse, mutect2, varscan2
- SLC8A3 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63527040; called by muse, mutect2, varscan2
- SLITRK6 | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1275192113, COSV68391844; called by muse, mutect2, varscan2
- SMAD1 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57473588; called by muse, mutect2, varscan2
- SNRPB | c.35A>G p.H12R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV60016683; called by muse, mutect2, varscan2
- SNX31 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 248/306 reads (81%) | catalogued as COSV61265136; called by muse, varscan2
- SORBS1 | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.218); catalogued as COSV53366586; called by muse, varscan2
- SYNE1 | c.19091A>G p.E6364G (on ENST00000367255 / NM_182961.4; = p.E6293G on NM_033071.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV55115141; called by muse, mutect2, varscan2
- SYT10 | c.1540T>A p.C514S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV57345963; called by muse, mutect2, varscan2
- TFAP2A | c.889G>T p.G297* (on ENST00000482890; = p.G289* on NM_001032280.3) | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV60237974; called by muse, varscan2
- TNR | c.1152G>C p.E384D | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV54915898; called by muse, mutect2, varscan2
- TNRC18 | c.3808G>A p.V1270M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs774003341, COSV68166088; called by muse, mutect2, varscan2
- TRMT6 | c.1252G>T p.G418* | Nonsense Mutation (SNP) | VAF 89/261 reads (34%) | catalogued as COSV52545820; called by muse, mutect2, varscan2
- TRPA1 | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV51557767, COSV51575144; called by muse, mutect2, varscan2
- TRPV6 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.167); catalogued as COSV63893883; called by muse, mutect2, varscan2
- TSGA10 | c.1159C>G p.Q387E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0.015); catalogued as COSV61825947; called by muse, mutect2, varscan2
- TTN | c.43548C>G p.D14516E (on ENST00000591111; = p.D7092E on NM_003319.4) | Missense Mutation (SNP) | VAF 140/332 reads (42%) | PolyPhen benign (0.043); catalogued as COSV60375059; called by muse, mutect2, varscan2
- UBFD1 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54843443; called by muse, mutect2, varscan2
- UGT2B4 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV59315316, COSV59321007; called by muse, mutect2
- USP38 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | catalogued as COSV61027595; called by muse, mutect2, varscan2
- USP51 | c.1643C>G p.S548* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as COSV72352020; called by muse, mutect2, varscan2
- VASH1 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV51335382, COSV99388192; called by muse, mutect2, varscan2
- ZCCHC2 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV54041445; called by muse, mutect2, varscan2
- ZFHX3 | c.908A>G p.H303R | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs750145538, COSV51738118; called by muse, mutect2, varscan2
- ZNF304 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56583982, COSV56586678; called by muse, mutect2, varscan2
- ZNF512B | c.1968+1G>T p.X656_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as COSV53879447; called by muse, mutect2, varscan2
- ZNF683 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV62876017; called by muse, mutect2, varscan2
- ZNF804A | c.2908C>G p.L970V | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV56473326; called by muse, mutect2, varscan2
- ATP13A3 | c.2930del p.L977Wfs*2 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- CYP11A1 | c.1388dup p.R465Tfs*5 | Frame Shift Ins (INS) | VAF 29/104 reads (28%) | called by mutect2, pindel, varscan2
- IMPG2 | c.3225del p.I1076Ffs*25 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | called by mutect2, pindel, varscan2
- MS4A14 | c.1360del p.Q454Kfs*35 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- PARP14 | c.4375dup p.S1459Kfs*2 | Frame Shift Ins (INS) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- SERPINA6 | c.1102del p.L368* | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- SLC27A6 | c.1497del p.I500Lfs*31 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- SLC40A1 | c.1228_1230del p.S410del | In Frame Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- ACSM5 | c.147G>T p.V49= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV59375273; called by muse, mutect2, varscan2
- CACNA1E | c.4869C>A p.I1623= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV62429555; called by muse, mutect2
- CD177 | c.270G>T p.R90= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV65122746; called by muse, mutect2, varscan2
- CD200R1 | c.234G>T p.L78= (on ENST00000471858 / NM_170780.3; = p.L101= on NM_138806.4) | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV55604426; called by muse, mutect2, varscan2
- CDH18 | c.1144C>T p.L382= | Silent (SNP) | VAF 63/109 reads (58%) | catalogued as COSV56924428, COSV56963965; called by muse, mutect2, varscan2
- CFAP20 | c.567C>T p.N189= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV52631639; called by muse, mutect2, varscan2
- CFAP70 | c.2685C>A p.I895= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV60287273; called by muse, mutect2, varscan2
- CLINT1 | c.1416C>T p.T472= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as rs559799646, COSV51629392; called by muse, mutect2, varscan2
- COL11A2 | c.2292C>T p.S764= (on ENST00000341947 / NM_080680.3; = p.S657= on NM_080679.2) | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV59503162; called by muse, mutect2, varscan2
- DEPDC1 | c.2052A>G p.Q684= (on ENST00000456315 / NM_001114120.3; = p.Q400= on NM_017779.6) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV63959415; called by muse, mutect2, varscan2
- EDEM3 | c.2298C>T p.F766= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV58928343; called by muse, mutect2, varscan2
- FTMT | c.657G>T p.G219= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV58421549; called by muse, mutect2, varscan2
- GABRB3 | c.207C>T p.I69= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs770214111, COSV54662945; called by muse, mutect2, varscan2
- GABRG3 | c.849A>G p.P283= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100409312, COSV61535132; called by muse, mutect2, varscan2
- GPR151 | c.291G>A p.T97= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as rs759311410, COSV57042441; called by muse, mutect2, varscan2
- GPR50 | c.1353C>A p.V451= | Silent (SNP) | VAF 271/666 reads (41%) | catalogued as COSV99506853; called by muse, varscan2
- HCRTR2 | c.153A>G p.K51= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as COSV63799395; called by muse, mutect2, varscan2
- HHIPL1 | c.846C>T p.I282= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV58093826; called by muse, mutect2, varscan2
- HMCN1 | c.15903A>G p.P5301= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV54941652, COSV54945057; called by muse, mutect2, varscan2
- HTR2C | c.324C>T p.P108= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as COSV52225771; called by muse, mutect2, varscan2
- KIF9 | c.1407C>T p.H469= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1214357553, COSV55523873; called by muse, mutect2, varscan2
- KRTAP19-2 | c.45G>A p.L15= | Silent (SNP) | VAF 71/176 reads (40%) | catalogued as rs149309849; called by muse, mutect2, varscan2
- LAD1 | c.402C>G p.S134= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV66213403; called by muse, mutect2, varscan2
- MANEAL | c.843C>G p.A281= (on ENST00000373045 / NM_001113482.1; = p.A59= on NM_152496.2) | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV61116968; called by muse, mutect2, varscan2
- MTUS2 | c.2265C>G p.V755= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV70923437; called by muse, mutect2, varscan2
- MUC17 | c.5676T>A p.A1892= | Silent (SNP) | VAF 124/404 reads (31%) | catalogued as COSV60305371; called by muse, mutect2, varscan2
- MYO3A | c.2853C>T p.C951= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs759388030, COSV56344728; called by muse, mutect2, varscan2
- MYO9A | c.6351T>C p.A2117= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV61858749; called by muse, mutect2
- OR10K1 | c.654C>T p.Y218= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as rs918006779, COSV56874494; called by muse, mutect2, varscan2
- OR4E2 | c.234G>T p.V78= | Silent (SNP) | VAF 103/284 reads (36%) | catalogued as COSV57732376; called by muse, mutect2, varscan2
- OR6C70 | c.180C>T p.F60= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV59245505; called by muse, mutect2, varscan2
- PCLO | c.15262C>T p.L5088= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV61670391; called by muse, mutect2, varscan2
- PDE1C | c.1569C>A p.A523= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV100374275; called by muse, mutect2, varscan2
- PHACTR2 | c.780A>G p.T260= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV59859846; called by muse, mutect2, varscan2
- PRAMEF20 | c.492C>T p.F164= | Silent (SNP) | VAF 171/483 reads (35%) | called by muse, mutect2, varscan2
- PRDM11 | c.426G>A p.R142= (on ENST00000530656 / NM_001359633.1; = p.R108= on NM_001256695.1) | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as COSV55444050, COSV99770325; called by muse, mutect2
- RAB40A | c.177C>T p.D59= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as rs1332331893, COSV58490882; called by muse, mutect2, varscan2
- RPN1 | c.342A>C p.T114= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99957377; called by muse, mutect2, varscan2
- SLITRK2 | c.1491C>A p.T497= | Silent (SNP) | VAF 51/212 reads (24%) | catalogued as COSV59429280; called by muse, mutect2, varscan2
- SOCS5 | c.1257C>T p.F419= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV60606592; called by muse, mutect2, varscan2
- SRMS | c.1263C>G p.T421= | Silent (SNP) | VAF 19/218 reads (9%) | catalogued as COSV53918662; called by muse, mutect2
- STAB2 | c.1845C>A p.L615= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV66347929; called by muse, mutect2, varscan2
- STK26 | c.309C>A p.G103= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as COSV61231266; called by muse, mutect2, varscan2
- SULT1B1 | c.399C>G p.A133= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60209663; called by muse, mutect2, varscan2
- SYT7 | c.657C>G p.L219= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV55659879; called by muse, mutect2, varscan2
- TBCE | c.564C>T p.L188= (on ENST00000366601; = p.L251= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as COSV64007819; called by muse, mutect2, varscan2
- TMEM132D | c.1567C>A p.R523= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs144267550, COSV67160505, COSV67160591, COSV67162685; called by muse, mutect2, varscan2
- TMEM61 | c.453T>A p.P151= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV64873991; called by muse, mutect2, varscan2
- TSPAN16 | c.567C>T p.D189= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs771425059, COSV57442414; called by muse, mutect2, varscan2
- UNC79 | c.3921G>T p.T1307= (on ENST00000393151 / NM_001346218.2; = p.T1130= on NM_020818.5) | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV56378393, COSV56413324; called by muse, mutect2, varscan2
- VPS13C | c.9402G>A p.Q3134= (on ENST00000644861 / NM_020821.3; = p.Q3091= on NM_017684.5) | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV51426976; called by muse, mutect2, varscan2
- VPS51 | c.894C>T p.P298= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1423349020, COSV54209306; called by muse, mutect2, varscan2
- XIRP2 | c.5901G>A p.K1967= (on ENST00000628543; = p.K2142= on NM_152381.6) | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV54737052; called by muse, mutect2
- BNC2 | c.2639+5624A>G | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101032118, COSV101034786; called by muse, mutect2, varscan2
- GNAO1 | c.723+7089G>T | Intron (SNP) | VAF 17/71 reads (24%) | catalogued as COSV52621097; called by muse, mutect2, varscan2
- OR6B1 | c.-1T>C | 5'UTR (SNP) | VAF 13/44 reads (30%) | catalogued as rs774367505, COSV101281680; called by muse, mutect2, varscan2
- PARGP1 | n.560G>C | RNA (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- PDE4DIP | c.637-6898C>T | Intron (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100522445; called by muse, mutect2, varscan2
- PLCD1 | c.35-4040G>T | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100587794; called by muse, mutect2, varscan2
- SSPOP | n.7268C>T | RNA (SNP) | VAF 19/60 reads (32%) | catalogued as COSV50489507; called by muse, mutect2, varscan2
